Somatic mutation profile of tumor specimen TCGA-BG-A0VT-01A (aliquot TCGA-BG-A0VT-01A-11D-A10M-09) from TCGA case TCGA-BG-A0VT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 56.4 years (20,602 days).
Specimen TCGA-BG-A0VT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57c8ec55-351e-4c43-bae7-d9dde7104993.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0VT-10A (Blood Derived Normal), aliquot TCGA-BG-A0VT-10A-01W-A124-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5666c57f-35d3-4cba-ac86-6ec54b608e1b

The open-access MAF lists 34 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Nonsense Mutation 4, Frame Shift Ins 2, Translation Start Site 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 46/59 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 40/101 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABI1 | c.465G>A p.W155* | Nonsense Mutation (SNP) | VAF 10/176 reads (6%) | catalogued as COSV100698046; called by muse, mutect2
- ALPK3 | c.2257A>G p.I753V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV51931328; called by muse, mutect2, varscan2
- CACNA1E | c.6499C>T p.R2167W (on ENST00000367573 / NM_001205293.3; = p.R2124W on NM_000721.4) | Missense Mutation (SNP) | VAF 68/113 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs763796830, COSV62386120; called by muse, mutect2, varscan2
- CD4 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs781997465, COSV50589600; called by muse, mutect2, varscan2
- CEACAM4 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55731044; called by muse, mutect2, varscan2
- CLTRN | c.245C>A p.S82* | Nonsense Mutation (SNP) | VAF 27/223 reads (12%) | catalogued as COSV58005093, COSV58005310; called by muse, mutect2, varscan2
- CREBBP | c.4545C>G p.I1515M | Missense Mutation (SNP) | VAF 138/423 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52117783; called by muse, mutect2, varscan2
- CYP11B1 | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.709); catalogued as COSV52824806, COSV52825753; called by muse, mutect2, varscan2
- EPPK1 | c.6418G>C p.V2140L | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.156); catalogued as rs892750826, COSV73260967; called by muse, mutect2, varscan2
- KCNMB2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs563719552, COSV64200625; called by muse, mutect2
- LILRB3 | c.1874C>T p.S625F (on ENST00000346401; = p.S613F on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV54432248; called by muse, mutect2, varscan2
- MGAT5B | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.042); catalogued as COSV56927095; called by muse, mutect2, varscan2
- NTSR1 | c.916+1G>A p.X306_splice | Splice Site (SNP) | VAF 12/20 reads (60%) | catalogued as rs764083183, COSV65138117, COSV65138272; called by muse, mutect2, varscan2
- OR6X1 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV60009535; called by muse, mutect2, varscan2
- PDPK1 | c.1538C>G p.T513S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.621); catalogued as COSV51912342; called by muse, mutect2, varscan2
- RNF112 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as rs775597035, COSV71327018; called by mutect2, varscan2
- RNF141 | c.361A>C p.S121R | Missense Mutation (SNP) | VAF 106/251 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as COSV56416505; called by muse, mutect2, varscan2
- RRP9 | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs749121006; called by muse, mutect2
- TMEM171 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 175/374 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55129751; called by muse, mutect2, varscan2
- TOR2A | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as rs914219202, COSV60160223; called by muse, mutect2, varscan2
- TRIML1 | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60193730, COSV60193855, COSV60194325; called by muse, mutect2, varscan2
- USH2A | c.14650G>A p.E4884K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV56343179; called by muse, mutect2, varscan2
- ZIC3 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54973037; called by muse, mutect2
- ZNF433 | c.644T>C p.I215T | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV61398732; called by muse, mutect2, varscan2
- ARID1A | c.2839_2840dup p.Y948Hfs*21 | Frame Shift Ins (INS) | VAF 52/154 reads (34%) | called by mutect2, pindel, varscan2
- CDKN1B | c.110_111dup p.H38Tfs*5 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- IL1RAPL1 | c.1974C>T p.N658= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs746058514, COSV56235055; called by muse, mutect2, varscan2
- ROPN1L | c.150G>A p.S50= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs781546950, COSV56873316; called by muse, mutect2, varscan2
- SHOX | c.6A>G p.E2= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as COSV61860456; called by muse, mutect2
- XPO6 | c.816C>T p.T272= | Silent (SNP) | VAF 76/221 reads (34%) | catalogued as COSV58964571; called by muse, mutect2, varscan2
- ZAN | c.3150C>T p.Y1050= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs1262302919, COSV61806797; called by muse, mutect2, varscan2
- RPGR | c.2520+106G>A | Intron (SNP) | VAF 287/809 reads (35%) | catalogued as COSV58833403; called by muse, mutect2, varscan2
